Gene-level copy-number profile of tumor specimen HCM-CSHL-0582-C18-06A from HCMI case HCM-CSHL-0582-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 56.2 years (20,518 days).
Specimen HCM-CSHL-0582-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 65cb3137-aa5c-4361-b937-d780cbfc3823.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0582-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,743 have no estimate.
https://portal.gdc.cancer.gov/files/b31728c8-9882-46a9-92ef-a3e862f083b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 1,708; copy number 2: 25,863; copy number 3: 20,848; copy number 4: 5,710; copy number 5: 3,306; copy number 6: 713; copy number 7: 582; copy number 11: 72; copy number 12: 60; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,471,765–1,497,848, 1 gene: ATAD3B.
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr4:68,614,419–68,670,652, 4 genes: AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr4:144,010,237–144,012,598, 1 gene (within-gene range 0–2): AC093890.2.
- chr16:5,838,131–5,838,661, 1 gene (within-gene range 0–1): AC012175.1.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–3): AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,734 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:266,855–675,265, 19 genes, copy number 5: AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6.
- chr1:12,791,397–12,831,410, 3 genes, copy number 5: PRAMEF1, LINC01784, PRAMEF11.
- chr1:149,903,318–193,186,613, 1,145 genes, copy number 5 (broad region; genes not listed).
- chr1:194,188,967–244,409,592, 988 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:244,454,377–248,937,043, 154 genes, copy number 5 (broad region; genes not listed).
- chr4:9,166,297–9,231,233, 7 genes, copy number 5: ALG1L14P, FAM90A26, USP17L10, USP17L11, USP17L12, USP17L13, USP17L14P.
- chr6:40,334,775–40,387,590, 1 gene, copy number 11 (within-gene range 4–11): TDRG1.
- chr6:40,358,744–48,701,872, 196 genes, copy number 5–12 (broad region; genes not listed).
- chr6:170,615,515–170,738,536, 1 gene, copy number 5 (within-gene range 2–5): AL672310.1.
- chr6:170,736,173–170,737,777, 1 gene, copy number 5: AL731684.1.
- chr7:9,082,557–19,002,416, 98 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:156,186,122–157,527,325, 27 genes, copy number 5: Y_RNA, AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4.
- chr12:42,069,935–42,144,874, 2 genes, copy number 5: AC023513.1, GXYLT1.
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 5–7 (broad region; genes not listed).
- chr16:33,802,764–33,803,217, 1 gene, copy number 15: IGHV3OR16-12.
- chr16:33,875,039–33,937,167, 2 genes, copy number 5: AC140658.3, ARHGAP23P1.
- chr16:33,976,039–34,051,363, 5 genes, copy number 5–7 (within-gene range 4–7): AC133561.1, BCAP31P1, AC133561.2, AC133561.4, AC133561.3.
- chr20:33,980,679–64,327,972, 753 genes, copy number 5 (broad region; genes not listed).
- chr21:12,999,676–13,016,692, 1 gene, copy number 5: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 1,704. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
